Surgical pathology report (de-identified scan), TCGA case TCGA-HW-7493, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-7493-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

history of seizures and non enhancing right temporal lobe mass.

Specimens Submitted:

- 1: SP: Right temporal brain tumor
- 2: SP: Right temporal brain tumor #2

DIAGNOSIS:

1. SP: RIGHT TEMPORAL BRAIN TUMOR

- Diffuse asdtrocytoma (WHO-II)
- MIB-1 reactivity is <3%

2. SP: RIGHT TEMPORAL BRAIN TUMOR #2:

- Diffuse asdtrocytoma (WHO-II)
- MIB-1 reactivity is <3%

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	MIB-1 (Ki-67)	
	IMM RECUT	
	NEG CONT	
	IMM RECUT	
	NEG CONT	
	RECUT	
	RECUT	
	RECUT	
	MIB-1 (Ki-67)	

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Right temporal brain tumor" and consists of two pieces of gray tan friable soft tissue measuring 0.8 cm and 1 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

[page 2 of 2]
2). The specimen is received fresh labeled, "right temporal brain tumor number two", and consists of multiple pieces of gray tan friable soft tissue measuring 3.8 x 2.0 x 0.7 cm in aggregate. The specimen is entirely submitted.

Summary of sections:
U-- undesignated

Summary of Sections:

Part 1: SP: Right temporal brain tumor [REDACTED]

Block	Sect. Site	PCs
1	fsc	1

Part 2: SP: Right temporal brain tumor #2

Block	Sect. Site	PCs
7	u	7

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: Right temporal brain tumor (fs): Astrocytoma, low-grade on representative section. [REDACTED]
PERMANENT DIAGNOSIS:

Source: NCI Genomic Data Commons file dd2e0d83-5e18-4286-9ac2-6bd9cf0a6ffd (TCGA-HW-7493.19B2A34C-33D1-49A2-AC5B-2775542FF1E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).